Somatic mutation profile of tumor specimen TCGA-EV-5903-01A (aliquot TCGA-EV-5903-01A-11D-1589-08) from TCGA case TCGA-EV-5903, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 57.2 years (20,888 days).
Specimen TCGA-EV-5903-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cef4314d-ad70-4612-aa5d-3bfd94fbc84b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EV-5903-10A (Blood Derived Normal), aliquot TCGA-EV-5903-10A-01D-1589-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/077662f7-d522-49ee-8c19-8b61a440b0f1

The open-access MAF lists 115 somatic variants for this specimen: 92 protein-altering or splice-affecting, 20 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 20, Frame Shift Del 7, Nonsense Mutation 5, Frame Shift Ins 2, In Frame Del 2, RNA 2, Splice Site 2, Intron 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA1 | c.1220C>A p.A407D | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV66070246, COSV66071909; called by muse, mutect2, varscan2
- ABI3BP | c.896T>G p.L299R | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.534); catalogued as COSV52550252; called by muse, mutect2
- ABL1 | c.331G>C p.V111L | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.594); catalogued as COSV59340334; called by muse, mutect2, varscan2
- ACSBG1 | c.821A>C p.N274T | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.363); catalogued as COSV51910418; called by muse, mutect2, varscan2
- AIPL1 | c.1067C>T p.T356I | Missense Mutation (SNP) | VAF 74/158 reads (47%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.005); catalogued as COSV51508887; called by muse, varscan2
- AK8 | c.1398C>G p.I466M | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV53760310; called by muse, mutect2
- ALDH16A1 | c.1681G>A p.G561S | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV53196534; called by muse, mutect2, varscan2
- ARHGEF28 | c.2137C>T p.Q713* | Nonsense Mutation (SNP) | VAF 4/27 reads (15%) | catalogued as rs1393670678, COSV55268641; called by muse, mutect2
- ARPC2 | c.436T>A p.Y146N | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55286440; called by muse, mutect2, varscan2
- ATP6V1B2 | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52355142; called by muse, mutect2, varscan2
- ATP8B3 | c.3183G>T p.K1061N | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV59548200; called by muse, mutect2, varscan2
- BPIFB2 | c.453C>G p.N151K | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV50070291; called by muse, mutect2, varscan2
- BRAT1 | c.206G>C p.S69T | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.378); catalogued as COSV61397276; called by muse, mutect2, varscan2
- C9orf72 | c.1313A>T p.D438V | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV66164020; called by muse, mutect2, varscan2
- CAPN15 | c.1487G>A p.G496E | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV54835760, COSV54839356; called by muse, mutect2, varscan2
- CDC40 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 47/164 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as rs948462247, COSV57012125; called by muse, mutect2, varscan2
- CLASP2 | c.4303C>A p.L1435I (on ENST00000359576; = p.L1434I on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.842); catalogued as COSV56293202; called by muse, mutect2, varscan2
- DCP1B | c.570C>G p.I190M | Missense Mutation (SNP) | VAF 65/194 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs765995440, COSV54972253; called by muse, mutect2, varscan2
- DDX47 | c.1112A>C p.D371A | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV61912067; called by muse, mutect2, varscan2
- DNAJB2 | c.725C>A p.S242* | Nonsense Mutation (SNP) | VAF 4/33 reads (12%) | catalogued as COSV99834325; called by muse, mutect2
- DNAJC5G | c.569A>T p.*190Lext*11 | Nonstop Mutation (SNP) | VAF 61/197 reads (31%) | catalogued as COSV56081178; called by muse, mutect2, varscan2
- ENPP4 | c.794T>G p.L265W | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.037); catalogued as COSV58089974; called by muse, mutect2, varscan2
- ERBB4 | c.2620G>T p.E874* | Nonsense Mutation (SNP) | VAF 48/172 reads (28%) | catalogued as COSV100724644, COSV100728622, COSV61505389; called by muse, mutect2, varscan2
- F2 | c.10G>A p.V4I | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.001); catalogued as rs766756950, COSV61317623; called by muse, mutect2, varscan2
- FBXO24 | c.119A>C p.Q40P (on ENST00000241071 / NM_033506.3; = p.Q78P on NM_012172.5) | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.898); catalogued as COSV53829234; called by muse, mutect2, varscan2
- FGF12 | c.280G>T p.D94Y (on ENST00000454309 / NM_021032.5; = p.D32Y on NM_004113.6) | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV53151142, COSV53190057; called by muse, varscan2
- FLCN | c.1277del p.I426Tfs*42 | Frame Shift Del (DEL) | VAF 5/40 reads (13%) | catalogued as COSV53257852; called by mutect2, varscan2*
- GLRX3 | c.530G>T p.S177I | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV58694391; called by muse, mutect2, varscan2
- IMMT | c.2272G>C p.E758Q | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.742); catalogued as COSV54482725; called by muse, mutect2, varscan2
- ITPR2 | c.2063T>A p.I688N | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV67275739; called by muse, mutect2, varscan2
- KHK | c.733T>C p.F245L | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as rs1159314704, COSV53151861; called by muse, mutect2, varscan2
- LAMB2 | c.5051C>T p.A1684V | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as COSV59737841; called by muse, mutect2, varscan2
- LCP2 | c.54C>G p.D18E | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as COSV50464060; called by muse, mutect2
- LRFN4 | c.1610T>A p.L537* | Nonsense Mutation (SNP) | VAF 11/25 reads (44%) | catalogued as COSV58922847; called by muse, mutect2, varscan2
- LRRC52 | c.526C>G p.L176V | Missense Mutation (SNP) | VAF 48/179 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV54233639; called by muse, mutect2, varscan2
- LRRC56 | c.1160C>T p.A387V | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.381); catalogued as COSV54246711; called by muse, mutect2, varscan2
- LTBP1 | c.1115A>C p.N372T (on ENST00000404816 / NM_206943.4; = p.N46T on NM_000627.4) | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63197389; called by muse, mutect2, varscan2
- MARS1 | c.802A>C p.I268L | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.768); catalogued as COSV56258556; called by muse, mutect2, varscan2
- NLRP11 | c.92C>A p.A31E | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.066); catalogued as COSV64088717; called by muse, mutect2, varscan2
- NUDT3 | c.198A>C p.E66D | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV74119442; called by muse, mutect2, varscan2
- NUP153 | c.253C>T p.H85Y | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.439); catalogued as COSV50463921; called by muse, mutect2, varscan2
- NUP188 | c.2641-1G>A p.X881_splice | Splice Site (SNP) | VAF 20/79 reads (25%) | catalogued as COSV65364731; called by muse, mutect2, varscan2
- OR4E2 | c.500C>G p.P167R | Missense Mutation (SNP) | VAF 53/172 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV57732281; called by muse, mutect2, varscan2
- PAPLN | c.3458T>C p.L1153S (on ENST00000554301; = p.L1126S on NM_173462.4) | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.416); catalogued as COSV53723481; called by muse, mutect2, varscan2
- PCF11 | c.1751A>T p.N584I | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.294); catalogued as rs1307424420, COSV53528037, COSV53537357; called by muse, mutect2, varscan2
- PCF11 | c.1965G>C p.E655D | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.541); catalogued as COSV53537375; called by muse, mutect2, varscan2
- PEBP1 | c.322G>T p.G108C | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54337862; called by muse, mutect2, varscan2
- PHF2 | c.811A>C p.I271L | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV63683717; called by muse, mutect2, varscan2
- PITRM1 | c.1852T>G p.F618V | Missense Mutation (SNP) | VAF 75/264 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV56539200; called by muse, mutect2, varscan2
- PMFBP1 | c.128A>G p.N43S | Missense Mutation (SNP) | VAF 76/172 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV52831465; called by muse, mutect2, varscan2
- POLQ | c.408G>T p.M136I | Missense Mutation (SNP) | VAF 74/272 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as COSV51760743; called by muse, mutect2, varscan2
- POLR3A | c.3700G>C p.A1234P | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.376); catalogued as COSV64932048; called by muse, mutect2, varscan2
- PSPC1 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.014); catalogued as COSV100142643; called by mutect2, varscan2
- RGL2 | c.1951A>G p.I651V | Missense Mutation (SNP) | VAF 135/406 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV65842929; called by muse, mutect2, varscan2
- RRS1 | c.1007G>A p.G336E | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as COSV52559015; called by muse, mutect2, varscan2
- RTL9 | c.2090T>G p.M697R | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT tolerated (0.25); PolyPhen benign (0.202); catalogued as COSV71825392, COSV71826326; called by muse, mutect2, varscan2
- SCIN | c.1427G>A p.G476D (on ENST00000297029 / NM_001112706.3; = p.G229D on NM_033128.3) | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745997710, COSV51698417; called by muse, mutect2, varscan2
- SHTN1 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.055); catalogued as COSV53387215; called by muse, mutect2
- SHTN1 | c.881T>C p.L294P | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53387235; called by muse, mutect2
- SKAP1 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61152384; called by muse, mutect2, varscan2
- SLC16A10 | c.264G>T p.Q88H | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.456); catalogued as COSV63235131; called by muse, mutect2, varscan2
- SLC2A13 | c.1189A>G p.S397G | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV55127811; called by muse, mutect2, varscan2
- SLC35G2 | c.195del p.R66Efs*18 | Frame Shift Del (DEL) | VAF 33/162 reads (20%) | catalogued as COSV67588676; called by mutect2, pindel, varscan2
- SLC6A13 | c.671G>C p.W224S | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV58260181; called by muse, mutect2, varscan2
- SON | c.1126T>C p.S376P | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.019); catalogued as COSV51670093; called by muse, mutect2, varscan2
- SPNS1 | c.361A>G p.R121G | Missense Mutation (SNP) | VAF 73/159 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57956654; called by muse, mutect2, varscan2
- SPON2 | c.289T>A p.F97I | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV52056469; called by muse, mutect2, varscan2
- SUGP2 | c.2509C>A p.L837I | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV58264941; called by muse, mutect2, varscan2
- SUPT16H | c.2920+1G>A p.X974_splice | Splice Site (SNP) | VAF 31/135 reads (23%) | catalogued as COSV52856795; called by muse, mutect2, varscan2
- TBC1D9 | c.2419A>G p.T807A | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.596); catalogued as COSV71308798; called by muse, mutect2
- TMEM161B | c.242T>C p.I81T | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as COSV56933966; called by muse, mutect2, varscan2
- TMEM186 | c.28A>G p.R10G | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.167); catalogued as COSV51634291; called by muse, mutect2, varscan2
- TMX3 | c.105T>G p.F35L | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV55187646; called by muse, mutect2, varscan2
- TNFSF10 | c.356C>G p.P119R | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.047); catalogued as COSV53844494; called by muse, mutect2, varscan2
- TPP1 | c.191T>G p.L64R | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.736); catalogued as COSV54999789; called by muse, mutect2, varscan2
- TRIM49 | c.63C>G p.Y21* | Nonsense Mutation (SNP) | VAF 12/40 reads (30%) | catalogued as COSV100316237; called by mutect2, varscan2
- USP20 | c.127T>A p.C43S | Missense Mutation (SNP) | VAF 56/196 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59618687; called by muse, mutect2, varscan2
- UTP25 | c.1494G>A p.M498I | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.315); catalogued as rs1458740851, COSV71966174; called by muse, mutect2, varscan2
- UVSSA | c.848A>C p.E283A | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.057); catalogued as COSV66230881; called by muse, mutect2, varscan2
- YEATS2 | c.3056T>C p.V1019A | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.098); catalogued as COSV59372145; called by muse, mutect2, varscan2
- ZNF184 | c.1321A>G p.T441A | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.386); catalogued as COSV53005586; called by muse, mutect2, varscan2
- ZNF207 | c.434C>A p.P145Q | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.367); catalogued as COSV58302028; called by muse, mutect2
- AP1G2 | c.52del p.A18Pfs*10 | Frame Shift Del (DEL) | VAF 13/61 reads (21%) | called by mutect2, pindel, varscan2
- DLEC1 | c.4880_4897del p.R1627_V1632del | In Frame Del (DEL) | VAF 7/57 reads (12%) | called by mutect2, pindel, varscan2
- FAM187B | c.98C>A p.A33D | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- MAP7 | c.754del p.S252Lfs*25 | Frame Shift Del (DEL) | VAF 20/108 reads (19%) | called by mutect2, pindel, varscan2
- NAV3 | c.3461dup p.H1155Pfs*9 | Frame Shift Ins (INS) | VAF 19/73 reads (26%) | called by mutect2, pindel, varscan2
- NFX1 | c.1886_1888del p.P629del | In Frame Del (DEL) | VAF 18/52 reads (35%) | called by mutect2, pindel, varscan2
- RINL | c.1600_1613del p.R534Qfs*14 (on ENST00000591812 / NM_001195833.2; = p.R420Qfs*14 on NM_198445.4) | Frame Shift Del (DEL) | VAF 22/102 reads (22%) | called by mutect2, pindel, varscan2
- SHPRH | c.1875del p.E626Nfs*11 | Frame Shift Del (DEL) | VAF 55/228 reads (24%) | called by mutect2, pindel, varscan2
- STRIP1 | c.1334_1335dup p.G446* | Frame Shift Ins (INS) | VAF 21/98 reads (21%) | called by mutect2, pindel, varscan2
- VPS9D1 | c.1354_1355del p.S452Pfs*48 | Frame Shift Del (DEL) | VAF 22/170 reads (13%) | called by pindel, varscan2
- CCIN | c.576C>T p.L192= | Silent (SNP) | VAF 30/76 reads (39%) | catalogued as COSV58725597; called by muse, mutect2, varscan2
- CSGALNACT2 | c.630A>G p.K210= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as COSV65676355; called by muse, mutect2, varscan2
- CWC22 | c.2340T>C p.P780= | Silent (SNP) | VAF 66/255 reads (26%) | catalogued as COSV55432231; called by muse, mutect2, varscan2
- DOP1A | c.6063T>A p.P2021= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV52717604, COSV52720093; called by muse, mutect2, varscan2
- EMC2 | c.186A>T p.A62= | Silent (SNP) | VAF 31/143 reads (22%) | catalogued as COSV55211215; called by muse, mutect2, varscan2
- FARP2 | c.3060G>C p.V1020= | Silent (SNP) | VAF 19/90 reads (21%) | catalogued as COSV50880870; called by muse, mutect2, varscan2
- HDAC4 | c.2943T>A p.I981= | Silent (SNP) | VAF 28/119 reads (24%) | catalogued as COSV61875568; called by muse, mutect2, varscan2
- HDAC6 | c.3288G>A p.R1096= | Silent (SNP) | VAF 11/16 reads (69%) | catalogued as rs782781030, COSV61930534; called by muse, mutect2, varscan2
- IMMP2L | c.234A>T p.S78= | Silent (SNP) | VAF 64/195 reads (33%) | catalogued as rs201012120, COSV59269483; called by muse, mutect2, varscan2
- LARP4B | c.2196T>C p.T732= | Silent (SNP) | VAF 27/98 reads (28%) | catalogued as rs780650567, COSV60223812; called by muse, mutect2, varscan2
- MIS18A | c.54G>A p.E18= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV51590539; called by muse, mutect2, varscan2
- MNAT1 | c.849T>C p.L283= | Silent (SNP) | VAF 43/128 reads (34%) | catalogued as COSV54195853; called by muse, mutect2, varscan2
- NIN | c.4845A>T p.T1615= (on ENST00000382041 / NM_182946.1; = p.T902= on NM_016350.4) | Silent (SNP) | VAF 154/501 reads (31%) | catalogued as COSV55405314; called by muse, mutect2, varscan2
- NSD1 | c.3642T>C p.L1214= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV61784133; called by muse, mutect2, varscan2
- OR51A7 | c.559C>T p.L187= | Silent (SNP) | VAF 47/148 reads (32%) | catalogued as rs773678445, COSV63788931; called by muse, mutect2, varscan2
- PATJ | c.4374C>T p.P1458= | Silent (SNP) | VAF 29/105 reads (28%) | catalogued as rs1296316747, COSV57171547; called by muse, mutect2, varscan2
- SLC35G6 | c.822C>T p.V274= | Silent (SNP) | VAF 27/184 reads (15%) | catalogued as COSV59495756; called by muse, varscan2
- SPATA31D1 | c.507G>A p.S169= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as rs753805850, COSV100783027, COSV61200978; called by muse, mutect2, varscan2
- ZNF341 | c.1890G>T p.A630= (on ENST00000375200 / NM_001282935.1; = p.A623= on NM_032819.4) | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV61008973, COSV61011124; called by muse, mutect2, varscan2
- ZNF836 | c.1539C>T p.L513= | Silent (SNP) | VAF 28/102 reads (27%) | catalogued as COSV59086394; called by muse, mutect2, varscan2
- ADGRL2 | c.3101+875C>T | Intron (SNP) | VAF 43/173 reads (25%) | catalogued as COSV99591411; called by muse, mutect2, varscan2
- DCHS2 | n.5379del | RNA (DEL) | VAF 36/186 reads (19%) | called by mutect2, pindel, varscan2
- SSPOP | n.10157G>A | RNA (SNP) | VAF 4/18 reads (22%) | catalogued as rs918307508, COSV65136714; called by muse, mutect2
